Somatic mutation profile of tumor specimen TCGA-ZJ-AAXT-01A (aliquot TCGA-ZJ-AAXT-01A-11D-A42O-09) from TCGA case TCGA-ZJ-AAXT, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 54.3 years (19,847 days).
Specimen TCGA-ZJ-AAXT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1bd7a8b8-1cc1-4a99-928c-2eef055927ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZJ-AAXT-10A (Blood Derived Normal), aliquot TCGA-ZJ-AAXT-10A-01D-A42R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1ca9529c-efd3-473f-9a23-15bb8a1946db

The open-access MAF lists 190 somatic variants for this specimen: 136 protein-altering or splice-affecting, 50 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 110, Silent 50, Nonsense Mutation 24, Intron 3, Splice Site 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.733C>T p.Q245* | Nonsense Mutation (SNP) | VAF 39/88 reads (44%) | catalogued as rs786202918, CM981673, COSV100910801, COSV64288504; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RB1 | c.297G>A p.W99* | Nonsense Mutation (SNP) | VAF 55/108 reads (51%) | catalogued as rs794727481, CM025391, COSV57294752; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.184G>T p.E62* | Nonsense Mutation (SNP) | VAF 14/56 reads (25%) | catalogued as rs1567556752, CM120852, COSV52811974, COSV52991347; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.3268C>G p.R1090G (on ENST00000404938 / NM_001163941.2; = p.R645G on NM_178559.6) | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV51706469, COSV99327743; called by muse, mutect2, varscan2
- ACAN | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as rs201105250, COSV61362457; called by muse, mutect2, varscan2
- ADAM18 | c.1022C>T p.T341I | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.041); catalogued as rs1393224729, COSV99695108; called by muse, mutect2, varscan2
- ADGRA3 | c.1646C>G p.S549C | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV99293046; called by muse, mutect2, varscan2
- AMPH | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.773); catalogued as COSV100340618, COSV57739638; called by muse, mutect2, varscan2
- APBB1 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as rs766381978, COSV54975389; called by muse, mutect2, varscan2
- ARAP3 | c.898C>T p.Q300* | Nonsense Mutation (SNP) | VAF 9/27 reads (33%) | catalogued as COSV99499431; called by muse, mutect2, varscan2
- ARHGEF40 | c.696T>A p.N232K | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.36); catalogued as COSV100070139; called by muse, mutect2, varscan2
- ASH1L | c.5692G>A p.E1898K | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV100853211; called by muse, mutect2, varscan2
- B2M | c.345G>A p.W115* | Nonsense Mutation (SNP) | VAF 61/111 reads (55%) | catalogued as COSV62566250; called by muse, mutect2, varscan2
- BAP1 | c.608C>G p.T203R | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99963583; called by muse, mutect2, varscan2
- BCORL1 | c.2662C>T p.Q888* | Nonsense Mutation (SNP) | VAF 12/24 reads (50%) | catalogued as COSV99498813; called by mutect2, varscan2
- BIVM-ERCC5 | c.1423C>T p.Q475* | Nonsense Mutation (SNP) | VAF 12/53 reads (23%) | catalogued as COSV99958613; called by muse, mutect2, varscan2
- BRIP1 | c.1246C>T p.R416W | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.048); catalogued as rs587780225, COSV99369601; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BTBD3 | c.691C>T p.Q231* | Nonsense Mutation (SNP) | VAF 8/31 reads (26%) | catalogued as COSV99655698; called by muse, mutect2, varscan2
- C19orf53 | c.201G>A p.M67I | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV55605858; called by muse, mutect2, varscan2
- CA11 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.935); catalogued as COSV99320531; called by muse, mutect2, varscan2
- CAD | c.4681G>C p.E1561Q | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.386); catalogued as COSV99254618; called by muse, mutect2, varscan2
- CBARP | c.622G>A p.E208K (on ENST00000382477; = p.E188K on NM_152769.3) | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs141808311; called by muse, mutect2, varscan2
- CCDC85A | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.232); catalogued as rs764849312, COSV68154259; called by muse, varscan2
- CDH10 | c.815-1G>A p.X272_splice | Splice Site (SNP) | VAF 6/14 reads (43%) | catalogued as COSV52580943; called by muse, mutect2, varscan2
- CHORDC1 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV100271928; called by muse, mutect2
- CHP1 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV100587027; called by muse, mutect2, varscan2
- CLSTN2 | c.1384G>T p.E462* | Nonsense Mutation (SNP) | VAF 20/67 reads (30%) | catalogued as COSV101515591; called by muse, mutect2, varscan2
- CNBD2 | c.1702C>T p.R568W (on ENST00000373973 / NM_001365709.1; = p.R564W on NM_080834.4) | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs373220798; called by muse, mutect2, varscan2
- CUL3 | c.1880T>G p.L627R | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100023921; called by muse, mutect2, varscan2
- DAAM2 | c.2005G>A p.E669K | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99224913; called by muse, mutect2, varscan2
- DDX49 | c.1270G>C p.D424H | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as COSV99650971; called by muse, mutect2, varscan2
- DIAPH1 | c.3580G>A p.D1194N | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs1002153995, COSV104389749, COSV99526042; called by muse, mutect2
- DIAPH3 | c.2306C>T p.S769L (on ENST00000400324 / NM_001042517.2; = p.S506L on NM_030932.3) | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.419); catalogued as COSV99933004, COSV99934038; called by muse, mutect2, varscan2
- DMD | c.4667G>C p.G1556A | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100818625; called by muse, mutect2
- DNAH10 | c.5494C>A p.Q1832K (on ENST00000409039; = p.Q1771K on NM_207437.3) | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101292096; called by muse, mutect2, varscan2
- DNASE2B | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as rs765373252, COSV101042055; called by muse, mutect2, varscan2
- DNHD1 | c.1744C>G p.L582V | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV99599621; called by muse, mutect2, varscan2
- DNMT3L | c.517G>C p.E173Q | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV99533192; called by muse, mutect2, varscan2
- DOCK6 | c.1291C>T p.R431W | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs747899374, COSV99370884; called by muse, mutect2, varscan2
- DPPA3 | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV100559844; called by muse, mutect2
- EDDM3B | c.228C>G p.I76M | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV100460783, COSV100460856; called by muse, mutect2, varscan2
- EHBP1L1 | c.2087C>T p.S696F | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV100499737, COSV58574180; called by muse, mutect2, varscan2
- ERF | c.1351G>C p.G451R | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.497); catalogued as COSV99724538; called by muse, varscan2
- FANCM | c.3412G>A p.E1138K | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV99950668; called by muse, mutect2, varscan2
- GOT1 | c.679C>T p.Q227* | Nonsense Mutation (SNP) | VAF 14/21 reads (67%) | catalogued as COSV65146987, COSV65147187; called by muse, mutect2, varscan2
- GPD1 | c.485G>C p.C162S | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.804); catalogued as COSV56547471, COSV99993747; called by muse, mutect2, varscan2
- GPRASP2 | c.1046G>A p.R349K | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.967); catalogued as COSV100176611; called by muse, mutect2, varscan2
- HEG1 | c.3739C>T p.Q1247* | Nonsense Mutation (SNP) | VAF 12/35 reads (34%) | catalogued as COSV100230212; called by muse, mutect2, varscan2
- IFNGR1 | c.955G>T p.E319* | Nonsense Mutation (SNP) | VAF 12/30 reads (40%) | catalogued as COSV100880815; called by muse, mutect2, varscan2
- IFNL1 | c.403C>T p.Q135* | Nonsense Mutation (SNP) | VAF 40/196 reads (20%) | catalogued as COSV100373619, COSV61317702; called by muse, mutect2, varscan2
- IL17RD | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.771); catalogued as rs200773591; called by muse, mutect2, varscan2
- IL1RAPL1 | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as rs763980117, COSV56312812; called by muse, mutect2, varscan2
- IQUB | c.2308G>C p.E770Q | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.383); catalogued as COSV100226865; called by muse, mutect2, varscan2
- ITGAV | c.298A>G p.I100V | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs201231113, COSV53715528, COSV53721051; called by muse, mutect2, varscan2
- ITGB6 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.248); catalogued as COSV99324258; called by muse, mutect2
- JMJD7-PLA2G4B | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT tolerated (0.06); PolyPhen benign (0.167); catalogued as COSV100583743; called by muse, mutect2, varscan2
- KCNE2 | c.225G>C p.K75N | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99285677; called by muse, mutect2, varscan2
- KIAA0753 | c.340G>C p.E114Q | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100810548; called by muse, mutect2, varscan2
- KIAA0895 | c.114G>C p.E38D | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV99766602; called by muse, mutect2, varscan2
- KIAA1210 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.629); catalogued as COSV101273974; called by muse, mutect2, varscan2
- KLK10 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.114); catalogued as COSV100010979; called by muse, mutect2, varscan2
- KMT2A | c.9848C>A p.P3283H | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as COSV100628268; called by muse, mutect2, varscan2
- KPNA5 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776342305, COSV100706128; called by muse, mutect2, varscan2
- LRP1B | c.4521G>C p.Q1507H | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV101254041; called by muse, varscan2
- LRP1B | c.4456G>C p.D1486H | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101254042; called by muse, varscan2
- MAP3K13 | c.2537C>T p.S846L | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV99406623; called by muse, mutect2, varscan2
- MARK2 | c.2185G>C p.E729Q (on ENST00000402010 / NM_001039469.2; = p.E665Q on NM_004954.5) | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); catalogued as COSV100036110; called by muse, mutect2, varscan2
- MBD4 | c.1460C>T p.S487L | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99998765; called by muse, mutect2, varscan2
- MDM1 | c.1502C>G p.S501* | Nonsense Mutation (SNP) | VAF 23/72 reads (32%) | catalogued as COSV57447306, COSV57448786; called by muse, mutect2, varscan2
- MKX | c.112C>T p.H38Y | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.053); catalogued as COSV101008597; called by muse, mutect2, varscan2
- MN1 | c.377C>A p.S126* | Nonsense Mutation (SNP) | VAF 7/12 reads (58%) | catalogued as COSV100179703, COSV56559005; called by muse, mutect2, varscan2
- MPRIP | c.2260C>T p.R754* | Nonsense Mutation (SNP) | VAF 18/66 reads (27%) | catalogued as COSV100505429; called by muse, mutect2, varscan2
- MYH6 | c.808G>C p.E270Q | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV100676374, COSV100676900; called by muse, mutect2, varscan2
- NBR1 | c.1099G>A p.V367I | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.204); catalogued as rs200135450; called by muse, mutect2, varscan2
- NLGN1 | c.1081G>C p.D361H | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100848899; called by muse, mutect2, varscan2
- OR4F4 | c.825G>C p.L275F | Missense Mutation (SNP) | VAF 42/240 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100055330; called by muse, mutect2, varscan2
- OR6M1 | c.896G>A p.R299K | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.91); PolyPhen benign (0.052); catalogued as COSV58433577; called by muse, varscan2
- OTOA | c.1895T>A p.M632K (on ENST00000286149; = p.M618K on NM_144672.4) | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as rs918377842, COSV99623916; called by muse, mutect2, varscan2
- PAMR1 | c.2150G>C p.R717T (on ENST00000619888 / NM_001001991.3; = p.R734T on NM_015430.4) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.156); catalogued as COSV99552262; called by muse, mutect2, varscan2
- PCDHGB2 | c.1564C>G p.H522D | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99533365; called by muse, mutect2, varscan2
- PHF8 | c.1858T>G p.L620V (on ENST00000357988 / NM_001184896.1; = p.L584V on NM_015107.3) | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100153924; called by muse, mutect2, varscan2
- PKD1L1 | c.3763G>A p.E1255K | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV99218894; called by muse, mutect2, varscan2
- PPARGC1A | c.1085C>G p.S362* | Nonsense Mutation (SNP) | VAF 11/29 reads (38%) | catalogued as COSV53525694; called by muse, mutect2, varscan2
- PPP1R1A | c.316G>C p.E106Q | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV54491258, COSV99226303; called by muse, mutect2, varscan2
- PPP1R7 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV52147301, COSV99297683; called by muse, mutect2
- PRPF38B | c.146T>C p.L49P | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100898228; called by muse, mutect2, varscan2
- PTHLH | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52367840; called by muse, mutect2, varscan2
- PTPN18 | c.784G>C p.D262H | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.588); catalogued as COSV51557814; called by muse, mutect2
- RBMXL1 | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as rs748002776, COSV99555750; called by muse, mutect2, varscan2
- RGL1 | c.914G>A p.R305K (on ENST00000360851 / NM_001297672.2; = p.R340K on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100486312; called by muse, mutect2, varscan2
- RNF19B | c.1768C>T p.Q590* | Nonsense Mutation (SNP) | VAF 17/50 reads (34%) | catalogued as COSV52390585, COSV99331211; called by muse, mutect2, varscan2
- RNF207 | c.1672G>T p.E558* | Nonsense Mutation (SNP) | VAF 7/32 reads (22%) | catalogued as COSV100658230; called by muse, mutect2, varscan2
- RRM2B | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs370367329; called by muse, mutect2, varscan2
- RXFP2 | c.1555G>C p.E519Q | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV53633843; called by muse, mutect2, varscan2
- RYR2 | c.12670G>C p.E4224Q | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.039); catalogued as COSV100768818, COSV63679907; called by mutect2, varscan2
- SAFB | c.1640C>G p.S547* | Nonsense Mutation (SNP) | VAF 28/83 reads (34%) | catalogued as COSV99412583; called by muse, mutect2, varscan2
- SAMD4B | c.2023C>A p.L675M | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99655645; called by muse, mutect2
- SCAF1 | c.2282C>G p.S761C | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as rs772383494, COSV100862076; called by muse, mutect2, varscan2
- SCFD2 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV101189305; called by muse, mutect2
- SEL1L2 | c.1495C>G p.L499V | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.883); catalogued as COSV53148211, COSV99532827; called by muse, mutect2, varscan2
- SELENOV | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.641); catalogued as COSV100112679; called by muse, mutect2, varscan2
- SF3A3 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.226); catalogued as COSV100885616; called by muse, mutect2, varscan2
- SLC22A9 | c.602C>T p.S201L | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV99654811; called by muse, mutect2, varscan2
- SLC25A23 | c.912G>C p.K304N | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99901997; called by muse, mutect2, varscan2
- SLC49A3 | c.439C>G p.P147A | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100448387; called by muse, mutect2, varscan2
- SNW1 | c.1216C>T p.Q406* | Nonsense Mutation (SNP) | VAF 19/42 reads (45%) | catalogued as COSV99473117; called by muse, mutect2, varscan2
- SPATA31D1 | c.1982G>C p.R661T | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.14); catalogued as COSV100782583, COSV61195412; called by muse, varscan2
- SPATA31D1 | c.2055G>C p.K685N | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV100782584, COSV61195072; called by muse, varscan2
- SYNE1 | c.13001G>A p.R4334K (on ENST00000367255 / NM_182961.4; = p.R4263K on NM_033071.3) | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV99556639; called by muse, mutect2, varscan2
- TCOF1 | c.2071G>A p.E691K (on ENST00000377797 / NM_001135243.1; = p.E614K on NM_000356.4) | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.542); catalogued as COSV100077031, COSV60350561; called by muse, mutect2, varscan2
- TEKT1 | c.445C>G p.L149V | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as COSV100106034; called by muse, mutect2, varscan2
- TFF1 | c.117G>C p.Q39H | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.382); catalogued as COSV52299304, COSV99367316; called by muse, mutect2, varscan2
- TMBIM1 | c.847G>C p.E283Q | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99297838; called by muse, varscan2
- TMC1 | c.1225-1G>C p.X409_splice | Splice Site (SNP) | VAF 23/71 reads (32%) | catalogued as COSV99918879; called by muse, mutect2, varscan2
- TMEM215 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as rs758132976, COSV100713146; called by muse, varscan2
- TOP3B | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100592392; called by muse, mutect2, varscan2
- TRDN | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as COSV100521163; called by muse, mutect2, varscan2
- TRPM3 | c.3766C>T p.R1256W (on ENST00000357533 / NM_001366142.2; = p.R1111W on NM_020952.6) | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs775326354, COSV62585125; called by muse, mutect2, varscan2
- USH2A | c.3089C>G p.S1030* | Nonsense Mutation (SNP) | VAF 17/57 reads (30%) | catalogued as COSV100231089; called by muse, mutect2, varscan2
- WDR44 | c.2018G>A p.R673H | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99561329; called by muse, mutect2, varscan2
- XRN1 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99377474; called by muse, mutect2, varscan2
- ZBTB3 | c.115C>T p.R39W | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs894838534, COSV67360784, COSV67361584; called by muse, mutect2, varscan2
- ZFHX3 | c.7783C>G p.Q2595E | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV51724466, COSV99195748; called by muse, mutect2, varscan2
- ZNF2 | c.732C>A p.C244* (on ENST00000611147 / NM_001291605.2; = p.C231* on NM_021088.4) | Nonsense Mutation (SNP) | VAF 18/79 reads (23%) | catalogued as COSV99728322; called by muse, mutect2, varscan2
- ZNF337 | c.14G>A p.G5E | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.072); catalogued as COSV99430080; called by muse, mutect2, varscan2
- ZNF407 | c.2488G>A p.D830N | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV99995117; called by muse, mutect2, varscan2
- ZNF460 | c.321G>C p.L107F | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100828042; called by muse, mutect2
- ZNF471 | c.927G>C p.Q309H | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as rs1301751444, COSV100340450; called by muse, mutect2, varscan2
- ZNF526 | c.106G>C p.E36Q | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.137); catalogued as COSV56631235; called by muse, mutect2, varscan2
- ZNF526 | c.631G>C p.E211Q | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as COSV100004361; called by muse, mutect2, varscan2
- ZNF526 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.034); catalogued as rs1395455772, COSV100004362; called by muse, mutect2, varscan2
- ZNF550 | c.408G>C p.Q136H | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.022); catalogued as COSV100286452; called by muse, mutect2, varscan2
- ZNF777 | c.2344G>A p.E782K | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.792); catalogued as COSV56097265; called by muse, mutect2, varscan2
- HGS | c.1945C>T p.Q649* | Nonsense Mutation (SNP) | VAF 5/42 reads (12%) | called by muse, mutect2
- IGHV4-28 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- LRP6 | c.4655C>A p.T1552K | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.025); called by muse, mutect2
- AL136295.1 | c.741C>T p.A247= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs373383253, COSV99937850; called by muse, mutect2, varscan2
- APOOL | c.339G>A p.P113= | Silent (SNP) | VAF 51/191 reads (27%) | catalogued as rs1367755665, COSV64271494; called by muse, mutect2, varscan2
- ASB6 | c.1215G>A p.L405= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs1275588834, COSV99475643; called by muse, mutect2
- AURKA | c.1122C>T p.L374= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as COSV100452852; called by muse, varscan2
- AURKA | c.1077C>T p.L359= | Silent (SNP) | VAF 30/76 reads (39%) | catalogued as COSV100452853; called by muse, varscan2
- BAAT | c.558C>T p.F186= | Silent (SNP) | VAF 29/100 reads (29%) | catalogued as rs760452448; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BBS7 | c.225C>T p.I75= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as COSV99144844; called by muse, mutect2, varscan2
- BICDL2 | c.1176G>A p.A392= | Silent (SNP) | VAF 23/89 reads (26%) | catalogued as rs755255015, COSV99560460; called by muse, mutect2, varscan2
- BUB1B | c.519G>A p.A173= | Silent (SNP) | VAF 22/75 reads (29%) | catalogued as COSV99806664; called by muse, mutect2, varscan2
- C2orf16 | c.4845C>T p.C1615= | Silent (SNP) | VAF 19/88 reads (22%) | catalogued as COSV100820710; called by muse, mutect2, varscan2
- CNTNAP4 | c.3414C>G p.V1138= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV100269963; called by muse, mutect2, varscan2
- DOP1B | c.6378G>T p.T2126= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV101215146; called by muse, mutect2, varscan2
- IL3RA | c.1035C>T p.I345= | Silent (SNP) | VAF 30/108 reads (28%) | catalogued as rs201211678, COSV100452219, COSV58430123, COSV58433847; called by muse, varscan2
- ITGA2B | c.2589C>G p.V863= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as rs781462273, COSV99288656; called by muse, mutect2, varscan2
- KLK10 | c.234G>A p.Q78= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV100010977; called by muse, mutect2, varscan2
- LLGL2 | c.2481G>A p.V827= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as rs202100751, COSV99389189; called by muse, mutect2, varscan2
- MAST1 | c.252G>A p.A84= | Silent (SNP) | VAF 29/107 reads (27%) | catalogued as rs778059086, COSV52246702; called by muse, mutect2, varscan2
- MYH11 | c.411G>A p.K137= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV100258050; called by muse, varscan2
- MYH11 | c.360C>G p.L120= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV100258051; called by muse, varscan2
- NAA20 | c.45C>T p.F15= | Silent (SNP) | VAF 23/83 reads (28%) | catalogued as COSV100131549; called by muse, mutect2, varscan2
- NAGA | c.9G>A p.L3= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as COSV100408889, COSV58791355; called by muse, mutect2, varscan2
- NES | c.75G>A p.R25= | Silent (SNP) | VAF 3/39 reads (8%) | catalogued as COSV100957793; called by muse, mutect2
- NIBAN2 | c.1479G>T p.R493= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV100031270; called by muse, mutect2, varscan2
- PCDHGA11 | c.189C>T p.R63= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV99533366; called by muse, mutect2, varscan2
- PCNX1 | c.2676A>T p.S892= | Silent (SNP) | VAF 30/96 reads (31%) | catalogued as COSV99454706; called by muse, mutect2, varscan2
- PITPNM1 | c.3546C>A p.P1182= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV99653584; called by muse, mutect2, varscan2
- PTPN13 | c.384C>G p.L128= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as COSV100364282; called by muse, mutect2, varscan2
- RCCD1 | c.249C>T p.L83= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV101263198; called by muse, mutect2, varscan2
- RTN1 | c.1362G>C p.L454= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV99954938; called by muse, mutect2, varscan2
- SF3A3 | c.171G>C p.L57= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV100885615, COSV65955470; called by muse, mutect2, varscan2
- SHPRH | c.450G>C p.L150= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as COSV99261543; called by muse, mutect2, varscan2
- SLC3A1 | c.975G>C p.L325= | Silent (SNP) | VAF 50/159 reads (31%) | catalogued as COSV99576888; called by muse, mutect2, varscan2
- SLC44A1 | c.1716G>C p.L572= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV100570258; called by muse, mutect2, varscan2
- SPRYD4 | c.621C>G p.L207= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV100358242; called by muse, mutect2, varscan2
- STAT3 | c.2019C>G p.L673= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as COSV99232552; called by muse, mutect2, varscan2
- SYNE3 | c.1482G>A p.E494= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as rs1304427006, COSV100515750; called by muse, mutect2, varscan2
- SYT5 | c.537C>T p.F179= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV100845874; called by muse, mutect2, varscan2
- SYTL1 | c.1233C>G p.A411= (on ENST00000543823; = p.A399= on NM_032872.3) | Silent (SNP) | VAF 25/81 reads (31%) | catalogued as rs1368854797, COSV100539214; called by muse, mutect2, varscan2
- TNS3 | c.573C>T p.F191= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as rs368113552; called by muse, mutect2, varscan2
- TRIM47 | c.1755C>A p.I585= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV99638380; called by muse, mutect2, varscan2
- TTC37 | c.1447C>T p.L483= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as COSV100706451; called by muse, mutect2, varscan2
- TUBA8 | c.471C>T p.L157= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV100283090; called by muse, mutect2, varscan2
- TUBGCP5 | c.2061G>A p.L687= | Silent (SNP) | VAF 25/75 reads (33%) | called by muse, mutect2, varscan2
- TXNDC8 | c.318C>T p.N106= | Silent (SNP) | VAF 21/81 reads (26%) | catalogued as rs763682901, COSV100995627; called by muse, mutect2, varscan2
- XK | c.1068C>G p.L356= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV101064568; called by muse, mutect2, varscan2
- ZFHX4 | c.7833G>A p.T2611= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as rs770762653, COSV51496115; called by muse, mutect2, varscan2
- ZFP36 | c.27G>C p.L9= (on ENST00000594442; = p.L3= on NM_003407.5) | Silent (SNP) | VAF 28/124 reads (23%) | catalogued as COSV99953698; called by muse, mutect2, varscan2
- ZNF358 | c.1089C>G p.L363= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as rs770876409, COSV99900467; called by muse, mutect2
- ZNF518B | c.3039C>G p.L1013= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV100456605; called by muse, mutect2, varscan2
- ZSWIM5 | c.552C>T p.I184= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV100655408; called by muse, mutect2, varscan2
- ADGRE4P | n.1113G>C | RNA (SNP) | VAF 9/52 reads (17%) | called by muse, mutect2, varscan2
- GABRA3 | c.-26-27682C>T | Intron (SNP) | VAF 9/23 reads (39%) | catalogued as COSV100942477; called by muse, mutect2, varscan2
- SH3TC1 | c.3131+330C>T | Intron (SNP) | VAF 7/30 reads (23%) | called by muse, mutect2, varscan2
- VPS13B | c.4820+15645G>A | Intron (SNP) | VAF 67/123 reads (54%) | catalogued as COSV100661163; called by muse, mutect2, varscan2
